Somatic mutation profile of tumor specimen C3N-00866-01 (aliquot CPT0063090009) from CPTAC case C3N-00866, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 77.3 years (28,243 days).
Specimen C3N-00866-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4adf604-4c66-42cf-8954-0e5e8320d109.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00866-71 (Blood Derived Normal), aliquot CPT0063210002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80a42ddb-f740-47f2-bb0f-ddcc9b91dbda

The open-access MAF lists 103 somatic variants for this specimen: 76 protein-altering or splice-affecting, 18 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 18, Nonsense Mutation 7, Intron 3, Frame Shift Del 3, In Frame Del 2, 5'Flank 2, RNA 2, 3'UTR 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133_135del p.S45del | In Frame Del (DEL) | VAF 125/444 reads (28%) | hotspot (GDC flag); catalogued as rs587776850; ClinVar: pathogenic / other; called by mutect2, pindel, varscan2
- MYH7 | c.3622G>A p.D1208N | Missense Mutation (SNP) | VAF 151/598 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs730880781, CM1411010; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1376_1378del p.K459del (on ENST00000521381 / NM_181523.3; = p.K189del on NM_181504.4) | In Frame Del (DEL) | VAF 24/63 reads (38%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 42/154 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AKT1 | c.238T>C p.W80R | Missense Mutation (SNP) | VAF 67/101 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV62571792, COSV62572815; called by muse, mutect2, varscan2
- ALAS2 | c.1549C>T p.R517C | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1569547781, CM095124, CM109572, COSV58189881; called by muse, mutect2, varscan2
- ARID1A | c.1820C>A p.S607* | Nonsense Mutation (SNP) | VAF 113/200 reads (57%) | catalogued as COSV61371220, COSV61386856; called by muse, mutect2, varscan2
- AXIN2 | c.550del p.E184Kfs*8 | Frame Shift Del (DEL) | VAF 78/274 reads (28%) | catalogued as COSV61060864; called by mutect2, pindel, varscan2
- BMP5 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 79/248 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.333); catalogued as rs144615410; called by muse, mutect2, varscan2
- C2CD2 | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 114/318 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.945); catalogued as rs149435261; called by muse, mutect2, varscan2
- CACHD1 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 94/257 reads (37%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.921); catalogued as rs1329242081, COSV51547183; called by muse, mutect2, varscan2
- CACNG7 | c.593A>G p.Y198C | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as COSV99711882; called by muse, mutect2, varscan2
- CTCF | c.1960C>T p.R654* | Nonsense Mutation (SNP) | VAF 13/111 reads (12%) | catalogued as COSV50498832; called by muse, mutect2, varscan2
- DGKG | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 77/250 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199698541; called by muse, mutect2, varscan2
- FAM135B | c.1138C>T p.R380W | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370662790, COSV99425981; called by muse, mutect2, varscan2
- FAT1 | c.2809C>T p.R937* | Nonsense Mutation (SNP) | VAF 54/175 reads (31%) | catalogued as rs547340067, COSV71672032; called by muse, mutect2, varscan2
- FGF21 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.63); catalogued as rs374501551; called by muse, mutect2, varscan2
- FTO | c.934G>A p.G312S | Missense Mutation (SNP) | VAF 111/433 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1567384728; called by muse, mutect2, varscan2
- GAS1 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 67/223 reads (30%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.796); catalogued as rs1260544074; called by muse, mutect2, varscan2
- HMGXB3 | c.1852C>G p.Q618E (on ENST00000613459; = p.Q372E on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as rs1381194623; called by muse, mutect2, varscan2
- HSPBAP1 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as rs142592436; called by muse, varscan2
- ILDR2 | c.1687G>A p.A563T | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs1416379592; called by muse, mutect2, varscan2
- KCNH5 | c.2216G>A p.R739H | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1483154649, COSV59763069; called by muse, mutect2, varscan2
- KCNJ16 | c.112C>T p.H38Y | Missense Mutation (SNP) | VAF 62/185 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV52251202; called by muse, mutect2, varscan2
- KLHL41 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1428920171; called by muse, mutect2, varscan2
- KMT2B | c.7531C>T p.R2511W | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55820488; called by muse, mutect2
- KRT83 | c.319G>A p.V107M | Missense Mutation (SNP) | VAF 56/767 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs143776387; called by muse, mutect2
- MED12 | c.5338G>A p.E1780K | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV61341372; called by muse, mutect2, varscan2
- NF2 | c.586C>G p.R196G | Missense Mutation (SNP) | VAF 84/285 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as CM950855, COSV58520570, COSV58525022; called by muse, mutect2, varscan2
- NOL4 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs755854498, COSV52347295; called by muse, mutect2, varscan2
- PCMTD2 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 118/367 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs769714581; called by muse, mutect2, varscan2
- PIK3R1 | c.1137del p.K379Nfs*2 (on ENST00000521381 / NM_181523.3; = p.K109Nfs*2 on NM_181504.4) | Frame Shift Del (DEL) | VAF 21/70 reads (30%) | catalogued as COSV57124239; called by mutect2, pindel, varscan2
- PITRM1 | c.2419A>G p.K807E | Missense Mutation (SNP) | VAF 69/237 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as rs368975326; called by muse, mutect2, varscan2
- PLEC | c.4927G>A p.E1643K (on ENST00000322810 / NM_201380.4; = p.E1533K on NM_000445.5) | Missense Mutation (SNP) | VAF 154/663 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1554702446; called by muse, mutect2, varscan2
- PLEC | c.2770C>T p.R924W (on ENST00000322810 / NM_201380.4; = p.R814W on NM_000445.5) | Missense Mutation (SNP) | VAF 57/323 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs782306099; called by muse, mutect2, varscan2
- PROX1 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV99800029; called by muse, mutect2
- PTEN | c.182A>T p.H61L | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs398123316, CM110129, COSV64290165, COSV64300390, COSV64310812; called by muse, mutect2, varscan2
- PTEN | c.650T>A p.V217D | Missense Mutation (SNP) | VAF 72/243 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as CM056377, COSV100910134, COSV64293433, COSV64310887; called by muse, mutect2, varscan2
- RPGRIP1L | c.2561G>A p.R854Q | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as rs867090245; called by muse, mutect2
- SAFB2 | c.2350C>T p.R784W | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368944878; called by muse, mutect2, varscan2
- SOX17 | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52025727; called by muse, mutect2, varscan2
- SREBF1 | c.3298G>A p.G1100S | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1480871634; called by muse, mutect2, varscan2
- TBC1D22B | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150222349; called by muse, mutect2, varscan2
- THOP1 | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373020872; called by muse, mutect2, varscan2
- TTN | c.100055C>T p.T33352M (on ENST00000591111; = p.T25928M on NM_003319.4) | Missense Mutation (SNP) | VAF 92/299 reads (31%) | PolyPhen benign (0.003); catalogued as rs368945564, COSV60067083; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TTN | c.78109G>A p.D26037N (on ENST00000591111; = p.D18613N on NM_003319.4) | Missense Mutation (SNP) | VAF 21/260 reads (8%) | PolyPhen probably damaging (0.998); catalogued as rs781128731; ClinVar: uncertain significance; called by muse, mutect2
- TTN | c.77552G>A p.R25851H (on ENST00000591111; = p.R18427H on NM_003319.4) | Missense Mutation (SNP) | VAF 18/281 reads (6%) | PolyPhen possibly damaging (0.855); catalogued as rs375752919; called by muse, mutect2
- WNK1 | c.3293C>G p.T1098R (on ENST00000315939 / NM_018979.4; = p.T851R on NM_014823.3) | Missense Mutation (SNP) | VAF 94/326 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV60037311; called by muse, varscan2
- WSCD2 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 65/164 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs567916978, COSV54578386; called by muse, mutect2, varscan2
- XIRP2 | c.4942G>T p.E1648* (on ENST00000628543; = p.E1823* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 49/161 reads (30%) | catalogued as rs528046000; called by muse, mutect2, varscan2
- ACTR1B | c.62T>A p.I21N | Missense Mutation (SNP) | VAF 51/200 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- AKAP10 | c.237C>A p.N79K | Missense Mutation (SNP) | VAF 71/225 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BRD4 | c.2977C>T p.P993S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- CARD10 | c.2516C>G p.P839R | Missense Mutation (SNP) | VAF 68/174 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- CASTOR2 | c.845T>G p.V282G | Missense Mutation (SNP) | VAF 56/622 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.322); called by muse, mutect2
- CCDC60 | c.276G>T p.E92D | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCL3L3 | c.215A>G p.Q72R | Missense Mutation (SNP) | VAF 156/950 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- CDSN | c.1249A>G p.S417G | Missense Mutation (SNP) | VAF 76/330 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- CEP126 | c.3146T>C p.L1049P | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- ELF3 | c.478+3dup | Splice Region (INS) | VAF 22/97 reads (23%) | called by mutect2, pindel
- FLT4 | c.823C>T p.R275W | Missense Mutation (SNP) | VAF 23/319 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- H3-3A | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 66/224 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.089); called by muse, varscan2
- IGHV3OR16-8 | c.290C>A p.S97* | Nonsense Mutation (SNP) | VAF 118/334 reads (35%) | called by muse, mutect2, varscan2
- LEMD2 | c.1304del p.R435Pfs*5 | Frame Shift Del (DEL) | VAF 108/386 reads (28%) | called by mutect2, pindel, varscan2
- LIX1L | c.273C>G p.H91Q | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- NEXMIF | c.3824G>A p.S1275N | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- PGAP6 | c.1645C>A p.L549M | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PKHD1L1 | c.5384A>G p.E1795G | Missense Mutation (SNP) | VAF 93/286 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RBM39 | c.394A>G p.R132G | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SARS1 | c.619C>T p.L207F | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SLCO3A1 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 89/314 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TMEM25 | c.731T>A p.L244H | Missense Mutation (SNP) | VAF 71/230 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- TNRC6B | c.1614G>A p.W538* | Nonsense Mutation (SNP) | VAF 19/292 reads (7%) | called by muse, mutect2
- TRIP11 | c.3543G>T p.Q1181H | Missense Mutation (SNP) | VAF 128/201 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ZNF750 | c.1777G>T p.G593W | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- ZNF829 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- ACSBG1 | c.861G>A p.G287= | Silent (SNP) | VAF 83/306 reads (27%) | catalogued as rs1463187713; called by muse, mutect2, varscan2
- ACTN3 | c.531C>T p.N177= | Silent (SNP) | VAF 40/118 reads (34%) | catalogued as rs762786709; called by muse, mutect2, varscan2
- AGPS | c.684T>C p.Y228= | Silent (SNP) | VAF 35/100 reads (35%) | catalogued as rs1156911145; called by muse, mutect2, varscan2
- AHNAK | c.4914C>T p.G1638= | Silent (SNP) | VAF 14/216 reads (6%) | called by muse, mutect2
- BEST2 | c.360C>T p.R120= | Silent (SNP) | VAF 22/139 reads (16%) | called by muse, mutect2, varscan2
- CBLL2 | c.924G>A p.S308= | Silent (SNP) | VAF 64/177 reads (36%) | catalogued as rs775002767; called by muse, mutect2, varscan2
- CIDEA | c.210C>T p.T70= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as rs148435881; called by muse, mutect2, varscan2
- DGKG | c.2199C>T p.C733= | Silent (SNP) | VAF 35/90 reads (39%) | catalogued as rs546201700, COSV53974226, COSV99404505; called by muse, mutect2, varscan2
- DIRAS3 | c.246C>T p.H82= | Silent (SNP) | VAF 90/248 reads (36%) | catalogued as rs376366084; called by muse, mutect2, varscan2
- DXO | c.138T>G p.P46= | Silent (SNP) | VAF 60/193 reads (31%) | catalogued as COSV61713331; called by muse, mutect2, varscan2
- INSR | c.2328G>A p.T776= | Silent (SNP) | VAF 25/266 reads (9%) | catalogued as rs758029294; called by muse, mutect2
- MYO18B | c.3864C>T p.S1288= | Silent (SNP) | VAF 91/250 reads (36%) | catalogued as rs143229909; called by muse, mutect2, varscan2
- PCDHB7 | c.2214C>T p.S738= | Silent (SNP) | VAF 37/355 reads (10%) | catalogued as COSV50758039, COSV50800092; called by muse, mutect2, varscan2
- RNF175 | c.834G>A p.E278= | Silent (SNP) | VAF 27/152 reads (18%) | called by muse, mutect2, varscan2
- SPATA17 | c.1038C>G p.L346= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV65121273; called by muse, mutect2, varscan2
- USP30 | c.39C>T p.A13= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs1483070656; called by muse, mutect2, varscan2
- ZNF154 | c.1248G>A p.T416= | Silent (SNP) | VAF 7/192 reads (4%) | catalogued as rs1490025462, COSV70744824; called by muse, mutect2
- ZNF473 | c.2004C>T p.H668= | Silent (SNP) | VAF 66/237 reads (28%) | catalogued as rs749475991; called by muse, mutect2, varscan2
- C1RL | c.*1253_*1260delinsAAAAAAAA | 3'UTR (ONP) | VAF 5/62 reads (8%) | called by mutect2*, pindel
- CCNYL2 | n.902C>T | RNA (SNP) | VAF 19/73 reads (26%) | catalogued as rs757608153; called by muse, mutect2, varscan2
- DCHS2 | n.210G>A | RNA (SNP) | VAF 19/166 reads (11%) | catalogued as rs376998218; called by muse, mutect2, varscan2
- FOXI2 | chr10:127736490 G>A | 5'Flank (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- GSTA4 | c.*5dup | 3'UTR (INS) | VAF 71/235 reads (30%) | called by mutect2, pindel, varscan2
- KCNIP3 | c.181+85G>T | Intron (SNP) | VAF 41/103 reads (40%) | called by muse, varscan2
- MTHFD2L | chr4:74157993 C>T | 5'Flank (SNP) | VAF 14/180 reads (8%) | called by muse, mutect2
- MUCL3 | c.947-300C>T | Intron (SNP) | VAF 13/191 reads (7%) | catalogued as rs767368704; called by muse, mutect2
- TFAM | c.594+66A>G | Intron (SNP) | VAF 55/160 reads (34%) | called by muse, mutect2, varscan2
